Somatic mutation profile of tumor specimen TCGA-AP-A0LO-01A (aliquot TCGA-AP-A0LO-01A-11W-A062-09) from TCGA case TCGA-AP-A0LO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 45.2 years (16,493 days).
Specimen TCGA-AP-A0LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c48e8b14-472e-4d8d-88e5-d47aaca3a452.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LO-10A (Blood Derived Normal), aliquot TCGA-AP-A0LO-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8136ca57-cf42-4fab-8154-6c212730d3b9

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1723_1731del p.K575_R577del (on ENST00000521381 / NM_181523.3; = p.K305_R307del on NM_181504.4) | In Frame Del (DEL) | VAF 37/203 reads (18%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 103/324 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 80/311 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM110142, COSV64288690, COSV64296946; called by muse, mutect2, varscan2
- ANKS1B | c.3440C>A p.A1147D (on ENST00000547776 / NM_152788.4; = p.A313D on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59120673; called by muse, mutect2, varscan2
- ARSG | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs764722003, COSV71593295; called by muse, mutect2, varscan2
- ASIC4 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749181230, COSV61732227; called by muse, mutect2, varscan2
- CCL25 | c.191+1G>A p.X64_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV53664439; called by muse, mutect2
- DHX16 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs370234964; called by muse, mutect2, varscan2
- FIG4 | c.629T>A p.I210N | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57788383; called by muse, mutect2, varscan2
- FRMPD4 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV101042176, COSV66216814; called by muse, mutect2, varscan2
- KRTAP20-2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 19/189 reads (10%) | PolyPhen benign (0.003); catalogued as rs1426063734, COSV58183402; called by muse, mutect2, varscan2
- METAP2 | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 123/447 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs200917784, COSV54149440; called by muse, mutect2, varscan2
- MYRF | c.1697G>A p.R566Q (on ENST00000278836 / NM_001127392.3; = p.R557Q on NM_013279.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV53889997; called by muse, mutect2, varscan2
- NFIL3 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as rs747568975, COSV52683490; called by muse, mutect2, varscan2
- OR2T1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs141385938, COSV63542173, COSV63542511; called by muse, mutect2, varscan2
- OR51G2 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1335585717, COSV58993497; called by muse, mutect2, varscan2
- PCDHA11 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554162740, COSV56513343; called by muse, mutect2, varscan2
- PLXNA3 | c.5203G>A p.V1735M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63754434, COSV63755672; called by muse, mutect2, varscan2
- SLC6A20 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV62071614; called by muse, mutect2, varscan2
- TMC3 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371581223; called by muse, mutect2, varscan2
- TMEM132B | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV54756802; called by muse, mutect2, varscan2
- TRAM1L1 | c.1033dup p.R345Kfs*13 | Frame Shift Ins (INS) | VAF 70/288 reads (24%) | catalogued as rs1237787070; called by mutect2, varscan2
- TTC21B | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV54631621; called by muse, mutect2, varscan2
- AHNAK2 | c.11296_11297del p.L3766Afs*16 | Frame Shift Del (DEL) | VAF 28/111 reads (25%) | called by pindel, varscan2
- IGHG4 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 92/656 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GARNL3 | c.372C>T p.S124= | Silent (SNP) | VAF 58/185 reads (31%) | catalogued as rs143970041, COSV59227541; called by muse, mutect2, varscan2
- MUSK | c.2283C>T p.N761= | Silent (SNP) | VAF 23/316 reads (7%) | catalogued as rs777419932, COSV51886287; called by muse, mutect2
- NEFL | c.720C>T p.Y240= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs58975336, COSV55337345; ClinVar: not provided / benign; called by muse, mutect2, varscan2
- PTPN20 | c.756C>T p.A252= | Silent (SNP) | VAF 202/769 reads (26%) | called by muse, mutect2, varscan2
- SEC16A | c.4830C>T p.A1610= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs149236979, COSV51530333; called by muse, mutect2, varscan2
- SPEG | c.4194C>T p.I1398= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs767998262, COSV56671292, COSV56676919; called by muse, mutect2, varscan2
- TMC4 | c.1437C>T p.V479= (on ENST00000617472 / NM_001145303.3; = p.V473= on NM_144686.4) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55827038, COSV55827568; called by muse, mutect2, varscan2
- UBXN7 | c.687C>T p.S229= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as rs368684662; called by muse, mutect2, varscan2
- VARS1 | c.1998G>A p.S666= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs765077498, COSV63304563; called by muse, mutect2, varscan2
